Somatic mutation profile of tumor specimen TCGA-FK-A4UB-01A (aliquot TCGA-FK-A4UB-01A-11D-A257-08) from TCGA case TCGA-FK-A4UB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.4 years (18,792 days).
Specimen TCGA-FK-A4UB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 586fcac1-0d93-4c8b-aa79-9c1fa85ba92a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A4UB-10A (Blood Derived Normal), aliquot TCGA-FK-A4UB-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/059d3f54-f420-4e05-ab32-ace7c097d5af

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASGEF1B | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100021239; called by muse, mutect2
- TRIP11 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV99971314; called by muse, mutect2, varscan2
- UNC13D | c.2282G>A p.R761H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs760020541, COSV99257835; called by muse, mutect2, varscan2
- FBXO7 | c.1106del p.P369Hfs*44 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- UBR4 | c.543C>T p.S181= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs761625091, COSV100922206; called by muse, mutect2, varscan2
